Somatic mutation profile of tumor specimen C3L-01967-02 (aliquot CPT0108750009) from CPTAC case C3L-01967, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 65.6 years (23,966 days).
Specimen C3L-01967-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc6a6f51-23b1-4d89-a566-735e5ce121af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01967-31 (Blood Derived Normal), aliquot CPT0108350002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea98cd37-18f8-4d0d-bf0b-ed64d6dc3788

The open-access MAF lists 177 somatic variants for this specimen: 130 protein-altering or splice-affecting, 30 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 113, Silent 30, Frame Shift Ins 8, Intron 6, 3'UTR 6, Splice Site 3, 5'UTR 3, Frame Shift Del 3, Splice Region 2, Nonsense Mutation 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KANSL1 | c.808_809del p.L270Vfs*11 | Frame Shift Del (DEL) | VAF 16/180 reads (9%) | catalogued as rs551541795; ClinVar: pathogenic; called by mutect2, pindel
- PKD1 | c.2494dup p.R832Pfs*40 | Frame Shift Ins (INS) | VAF 33/372 reads (9%) | catalogued as rs1567210630; ClinVar: pathogenic; called by mutect2, pindel
- ARHGEF10 | c.3992C>T p.A1331V (on ENST00000398564; = p.A1306V on NM_014629.4) | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375455536; called by muse, mutect2
- ATRX | c.4754C>A p.S1585Y | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64872748; called by muse, mutect2
- BCHE | c.1333T>C p.F445L | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); catalogued as rs752486524; called by muse, mutect2
- CCDC58 | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV52247786; called by muse, mutect2
- CDH10 | c.1655dup p.N552Kfs*5 | Frame Shift Ins (INS) | VAF 17/162 reads (10%) | catalogued as rs754722288; called by mutect2, pindel
- CLCN3 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61627170; called by muse, mutect2
- CNTN1 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61644132; called by muse, mutect2
- CORO1C | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.051); catalogued as rs754176044; called by muse, mutect2
- CPNE1 | c.1166C>A p.T389N (on ENST00000352393; = p.T394N on NM_003915.5) | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480743469; called by muse, mutect2
- DCAF4L2 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 31/383 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60477844, COSV60483126; called by muse, mutect2
- DDX17 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs1347509001; called by muse, mutect2
- DPAGT1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 36/551 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs1364757563, COSV100830703; called by muse, mutect2
- E2F1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs864622017, COSV58534885; ClinVar: uncertain significance; called by muse, mutect2
- ESRRA | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as rs1340972600, COSV50004946; called by muse, mutect2
- ING1 | c.1232T>C p.L411P | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100312336; called by muse, mutect2
- KCNA4 | c.663del p.F221Lfs*21 | Frame Shift Del (DEL) | VAF 28/277 reads (10%) | catalogued as rs754892524; called by mutect2, pindel
- LLPH | c.86T>C p.L29P | Missense Mutation (SNP) | VAF 25/323 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56981330, COSV56981722; called by muse, mutect2
- MUC12 | c.1546T>A p.F516I (on ENST00000379442; = p.F373I on NM_001164462.1) | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.702); catalogued as COSV65207610; called by muse, mutect2
- MYCBP2 | c.11753T>A p.I3918K (on ENST00000357337; = p.I3956K on NM_015057.5) | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62011105; called by muse, mutect2
- NAGS | c.654dup p.G219Wfs*77 | Frame Shift Ins (INS) | VAF 22/286 reads (8%) | catalogued as rs1256337877; called by mutect2, pindel
- NCKAP5 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 22/287 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs186998842; called by muse, mutect2
- PCDHB3 | c.1880C>T p.A627V | Missense Mutation (SNP) | VAF 46/624 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.543); catalogued as rs1554272600; called by muse, mutect2
- PIK3R1 | c.1700A>C p.K567T (on ENST00000521381 / NM_181523.3; = p.K297T on NM_181504.4) | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV104387195; called by muse, mutect2
- PTPN14 | c.3161C>T p.T1054M | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189546585; called by muse, mutect2
- RHOU | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 23/388 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.352); catalogued as rs764760417, COSV64209313; called by muse, mutect2
- RNF123 | c.2048G>A p.R683H | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373109530; called by muse, mutect2
- RPS9 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs753088540; called by muse, mutect2
- SEPTIN6 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100595554; called by muse, mutect2
- SHD | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs753515858; called by muse, mutect2
- SMARCB1 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 40/562 reads (7%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1268653633, CM025203, COSV54095922; called by muse, mutect2
- SSTR5 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 35/539 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs139275069; called by muse, mutect2
- STK3 | c.43A>G p.N15D | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1277120825; called by muse, mutect2
- TCF7L2 | c.1001+1G>A p.X334_splice (on ENST00000355995 / NM_001367943.1; = p.X311_splice on NM_030756.5) | Splice Site (SNP) | VAF 12/149 reads (8%) | catalogued as rs1477809102, COSV53335999; called by muse, mutect2
- TNFAIP8L1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1333744732; called by muse, mutect2
- TTC7B | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 35/462 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as rs752322173; called by muse, mutect2
- TTI1 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs1274711872; called by muse, mutect2
- TTYH3 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460914764; called by muse, mutect2
- WDR7 | c.1907G>C p.S636T | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as rs1568163517; called by muse, mutect2
- YME1L1 | c.2254A>G p.T752A (on ENST00000326799 / NM_139312.3; = p.T695A on NM_014263.4) | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as rs573706235; called by muse, mutect2
- ZFP91 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60158747; called by muse, mutect2
- ZNF202 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.544); catalogued as rs372622047; called by muse, mutect2
- ABI3BP | c.1361A>G p.Q454R | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- ADGRA2 | c.2018dup p.V674Rfs*31 | Frame Shift Ins (INS) | VAF 14/155 reads (9%) | called by mutect2, pindel
- ALG8 | c.731T>A p.V244D | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); called by muse, mutect2
- APP | c.1374G>A p.M458I | Missense Mutation (SNP) | VAF 28/341 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.273); called by muse, mutect2
- C2orf16 | c.231G>C p.Q77H | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- CACNA1F | c.2167G>T p.A723S | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- CAMK2A | c.515-2A>C p.X172_splice | Splice Site (SNP) | VAF 15/132 reads (11%) | called by muse, mutect2, varscan2
- CD3D | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.162); called by muse, mutect2
- CDH10 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); called by muse, mutect2
- CIDEA | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.972); called by muse, mutect2
- COL16A1 | c.826A>G p.T276A | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2
- CORIN | c.2698G>T p.E900* | Nonsense Mutation (SNP) | VAF 24/429 reads (6%) | called by muse, mutect2
- CPNE2 | c.1192T>C p.Y398H | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DAPL1 | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.108); called by muse, mutect2
- DBT | c.1378A>C p.M460L | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2
- DHX9 | c.2196C>T p.C732= | Splice Region (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- DIAPH2 | c.2890A>G p.M964V | Missense Mutation (SNP) | VAF 25/330 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.204); called by muse, mutect2
- DLG3 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DLL1 | c.509A>G p.D170G | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); called by muse, mutect2
- DNAJC10 | c.1551+2T>C p.X517_splice | Splice Site (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2
- EBF4 | c.206T>G p.F69C (on ENST00000609451; = p.F65C on NM_001110514.1) | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EP300 | c.3415T>A p.Y1139N | Missense Mutation (SNP) | VAF 34/508 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ERH | c.23T>A p.V8E | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ERMP1 | c.1305A>T p.K435N | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- FKBP3 | c.353A>G p.K118R | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); called by muse, mutect2
- FLG | c.1072A>G p.T358A | Missense Mutation (SNP) | VAF 32/517 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.298); called by muse, mutect2
- FZD2 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.02); called by muse, mutect2
- GCK | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2
- GRID2 | c.557A>C p.D186A | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- HIC1 | c.871C>T p.P291S (on ENST00000322941 / NM_001098202.1; = p.P272S on NM_006497.4) | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.092); called by muse, mutect2
- HMCN1 | c.9436A>G p.N3146D | Missense Mutation (SNP) | VAF 44/426 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- HOXA5 | c.274T>C p.S92P | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.401); called by muse, mutect2
- IFT80 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2
- IGSF10 | c.4405A>C p.S1469R | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- IQCB1 | c.806A>C p.E269A | Missense Mutation (SNP) | VAF 35/300 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ITGA3 | c.1921A>C p.R641= | Splice Region (SNP) | VAF 26/255 reads (10%) | called by muse, mutect2, varscan2
- JADE3 | c.1748A>G p.Q583R | Missense Mutation (SNP) | VAF 36/510 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- KIAA0100 | c.4463T>C p.L1488P | Missense Mutation (SNP) | VAF 24/459 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIF7 | c.2396T>C p.V799A | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2
- KRTAP15-1 | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.046); called by muse, mutect2
- LINGO1 | c.823C>A p.L275M | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- LRP1B | c.2278T>C p.S760P | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MET | c.4079A>T p.K1360I | Missense Mutation (SNP) | VAF 28/506 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.292); called by muse, mutect2
- MYO6 | c.1699G>T p.V567F | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.175); called by muse, mutect2
- NAV1 | c.2290A>G p.T764A | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.067); called by muse, mutect2
- NEK2 | c.689A>G p.E230G | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.051); called by muse, mutect2
- NUP160 | c.4196A>C p.N1399T | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- OR52D1 | c.499A>G p.R167G | Missense Mutation (SNP) | VAF 31/301 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PARP9 | c.1609A>C p.I537L | Missense Mutation (SNP) | VAF 22/294 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2
- PCDH9 | c.1501A>G p.N501D | Missense Mutation (SNP) | VAF 17/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PGC | c.813C>G p.C271W | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PHOX2B | c.530A>G p.D177G | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- PNKP | c.350A>T p.D117V | Missense Mutation (SNP) | VAF 42/615 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2
- POLR2H | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 24/333 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.201); called by muse, mutect2
- PPP1R13B | c.65T>C p.I22T | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2
- PSMC1 | c.824A>C p.E275A | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- RAB3IP | c.1367A>T p.E456V (on ENST00000550536 / NM_175623.4; = p.E440V on NM_022456.5) | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RAC1 | c.479T>A p.L160H | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- RANBP6 | c.912dup p.H305Tfs*18 | Frame Shift Ins (INS) | VAF 20/230 reads (9%) | called by mutect2, pindel
- RAPGEFL1 | c.1295T>C p.L432P | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RB1 | c.62dup p.A22Gfs*9 | Frame Shift Ins (INS) | VAF 16/178 reads (9%) | called by mutect2, pindel
- RB1 | c.2622dup p.L875Tfs*4 | Frame Shift Ins (INS) | VAF 41/491 reads (8%) | called by mutect2, pindel
- RNF169 | c.1018G>C p.A340P | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SETDB1 | c.2558A>T p.Y853F | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SIN3B | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.91); PolyPhen benign (0.006); called by muse, mutect2
- SOX3 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.535); called by muse, mutect2
- SSBP4 | c.662dup p.P222Tfs*57 | Frame Shift Ins (INS) | VAF 10/99 reads (10%) | called by mutect2, pindel
- STK19 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2
- TAOK2 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 24/415 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.125); called by muse, mutect2
- TAS1R1 | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2
- TFCP2L1 | c.526T>A p.F176I | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TIMD4 | c.1051A>G p.R351G | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- TNF | c.458C>A p.T153N | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2
- TNPO1 | c.858A>T p.E286D | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.289); called by muse, mutect2
- TPCN2 | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 11/197 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- TTN | c.85733T>G p.V28578G (on ENST00000591111; = p.V21154G on NM_003319.4) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | PolyPhen possibly damaging (0.654); called by muse, mutect2
- UBQLN3 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- UTP23 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- UTP4 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.11); called by muse, mutect2
- UTRN | c.9839A>T p.E3280V | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VASP | c.40A>G p.M14V | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2
- XBP1 | c.503del p.R168Nfs*27 | Frame Shift Del (DEL) | VAF 10/116 reads (9%) | called by mutect2, pindel
- ZNF37A | c.185A>C p.K62T | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- ZNF560 | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- ZNF658 | c.2472A>C p.K824N | Missense Mutation (SNP) | VAF 28/501 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZNF684 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF827 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2
- ADAMDEC1 | c.732T>C p.F244= | Silent (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- ADAR | c.1413T>C p.G471= | Silent (SNP) | VAF 18/249 reads (7%) | called by muse, mutect2
- AKAIN1 | c.129C>T p.R43= | Silent (SNP) | VAF 12/218 reads (6%) | catalogued as rs1459552704; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.1467A>G p.L489= | Silent (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- CCDC191 | c.1431T>G p.P477= | Silent (SNP) | VAF 15/185 reads (8%) | called by muse, mutect2
- COL1A1 | c.2217A>G p.P739= | Silent (SNP) | VAF 18/308 reads (6%) | catalogued as rs1347653426; called by muse, mutect2
- DYNC1H1 | c.10536G>A p.A3512= | Silent (SNP) | VAF 34/556 reads (6%) | catalogued as rs1060504512, COSV100794792; ClinVar: likely benign; called by muse, mutect2
- FBN3 | c.5013G>A p.R1671= | Silent (SNP) | VAF 17/189 reads (9%) | called by muse, mutect2
- GABRB3 | c.627G>A p.P209= | Silent (SNP) | VAF 44/654 reads (7%) | catalogued as rs146431931, COSV54648742; called by muse, mutect2
- GAS7 | c.969C>T p.A323= (on ENST00000432992 / NM_201433.2; = p.A183= on NM_003644.3) | Silent (SNP) | VAF 19/265 reads (7%) | catalogued as rs774856674, COSV60435975; called by muse, mutect2
- HMCN1 | c.15126C>T p.T5042= | Silent (SNP) | VAF 32/358 reads (9%) | catalogued as rs148569971; called by muse, mutect2
- IDS | c.414C>T p.H138= | Silent (SNP) | VAF 32/446 reads (7%) | catalogued as COSV61714053; called by muse, mutect2
- KMT2C | c.3897A>G p.K1299= | Silent (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- LAMA3 | c.1449A>G p.P483= | Silent (SNP) | VAF 24/300 reads (8%) | catalogued as rs1416048772; called by muse, mutect2
- LRGUK | c.1494A>G p.V498= | Silent (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- MED12L | c.4167T>C p.A1389= | Silent (SNP) | VAF 15/216 reads (7%) | called by muse, mutect2
- MGAT3 | c.1404G>A p.T468= | Silent (SNP) | VAF 26/290 reads (9%) | catalogued as rs758299553, COSV57865638; called by muse, mutect2
- MYO3B | c.762T>C p.P254= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as rs1558900954; called by muse, mutect2
- NTRK3 | c.2379A>G p.R793= (on ENST00000360948 / NM_001012338.2; = p.R779= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as rs774954330; called by muse, mutect2
- OR2F1 | c.301T>C p.L101= | Silent (SNP) | VAF 12/320 reads (4%) | called by muse, mutect2
- PAIP2B | c.252A>G p.G84= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- PCDHGA8 | c.408A>G p.E136= | Silent (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- PFKFB1 | c.1404A>G p.P468= | Silent (SNP) | VAF 29/318 reads (9%) | catalogued as rs1203822019; called by muse, mutect2
- PHTF2 | c.1566T>C p.A522= (on ENST00000248550 / NM_001366089.1; = p.A484= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 25/373 reads (7%) | called by muse, mutect2
- PLXNA2 | c.834A>G p.S278= | Silent (SNP) | VAF 17/206 reads (8%) | called by muse, mutect2
- POMGNT1 | c.507C>T p.P169= | Silent (SNP) | VAF 23/396 reads (6%) | catalogued as rs576860809; ClinVar: likely benign; called by muse, mutect2
- POU3F3 | c.1096C>T p.L366= | Silent (SNP) | VAF 28/313 reads (9%) | called by muse, mutect2
- RUNX1 | c.1149G>A p.S383= (on ENST00000344691 / NM_001001890.3; = p.S410= on NM_001754.5) | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as rs771529157, COSV100277872; ClinVar: uncertain significance; called by muse, mutect2
- SEMA6A | c.2817T>C p.T939= | Silent (SNP) | VAF 15/332 reads (5%) | catalogued as rs1264955061; called by muse, mutect2
- TAS2R50 | c.168T>C p.I56= | Silent (SNP) | VAF 7/148 reads (5%) | called by muse, mutect2
- BHMT | c.-41G>A | 5'UTR (SNP) | VAF 12/148 reads (8%) | catalogued as rs1398983399, COSV99165473; called by muse, mutect2
- CCDC22 | c.-56C>A | 5'UTR (SNP) | VAF 22/308 reads (7%) | called by muse, mutect2
- CSGALNACT1 | c.*1344dup | 3'UTR (INS) | VAF 17/124 reads (14%) | called by mutect2, pindel, varscan2
- DHFR | c.*48dup | 3'UTR (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- HTRA2 | c.939+48T>C | Intron (SNP) | VAF 36/556 reads (6%) | called by muse, mutect2
- KCNE3 | c.*12T>C | 3'UTR (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- LVRN | c.*42T>C | 3'UTR (SNP) | VAF 22/239 reads (9%) | called by muse, mutect2
- LYST | c.8359-14T>C | Intron (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- MAP1B | c.511-562C>A | Intron (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- MTND6P20 | chr8:46841073 T>C | 3'Flank (SNP) | VAF 12/165 reads (7%) | called by muse, mutect2
- NDUFS1 | c.-5+162G>A | Intron (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- RPL31P57 | n.121C>T | RNA (SNP) | VAF 16/298 reads (5%) | catalogued as rs1320407303; called by muse, mutect2
- RSL24D1 | c.81+438del | Intron (DEL) | VAF 22/264 reads (8%) | called by mutect2, pindel
- TYROBP | c.*147A>G | 3'UTR (SNP) | VAF 11/148 reads (7%) | called by muse, mutect2
- USP46 | c.*13C>T | 3'UTR (SNP) | VAF 14/250 reads (6%) | catalogued as rs1478922707, COSV71513200; called by muse, mutect2
- ZNF471 | c.-22A>C | 5'UTR (SNP) | VAF 14/166 reads (8%) | catalogued as rs1349302270; called by muse, mutect2
- ZNF565 | c.256+91T>C | Intron (SNP) | VAF 13/175 reads (7%) | called by muse, mutect2
